Gene-level copy-number profile of specimen HCM-BROD-0681-C71-85R from HCMI case HCM-BROD-0681-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.2 years (18,343 days).
Specimen HCM-BROD-0681-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 987a15c8-279b-43d4-8077-82fd5aa5f561.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0681-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/6dd9a7df-1ebf-455c-9ee3-caf46b86e910

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 28; copy number 2: 7,825; copy number 3: 1,882; copy number 4: 41,142; copy number 5: 1,685; copy number 6: 5,886; copy number 7: 111; copy number 8: 254; copy number 10: 4; copy number 11: 3; copy number 75: 11; copy number 78: 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–22,128,103, 1 gene (within-gene range 0–2): CDKN2B-AS1.
- chr9:22,046,758–30,690,272, 64 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:66,797,741–66,801,256, 1 gene, copy number 78: INSL5.
- chr7:54,621,025–55,344,958, 11 genes, copy number 75: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr7:64,735,933–64,833,681, 4 genes, copy number 10: AC091799.1, AC073349.3, ZNF138, AC073349.4.
- chr9:43,109,866–60,547,154, 3 genes, copy number 11: FP325317.1, FP325317.2, BX088702.1.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
